Somatic mutation profile of tumor specimen C3N-03426-01 (aliquot CPT0226600007) from CPTAC case C3N-03426, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 68.4 years (24,994 days).
Specimen C3N-03426-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9bcd66f-47db-426b-a53b-6005a39eae91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03426-31 (Blood Derived Normal), aliquot CPT0226640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8948b88c-b6fc-4eb0-82de-ba5d959202c8

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 25 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 25, Intron 5, RNA 4, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Splice Region 1, 5'Flank 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 72/564 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AIMP2 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 72/682 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56151716; called by muse, mutect2, varscan2
- ALMS1 | c.5015T>C p.V1672A | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as rs1311871252; called by muse, mutect2, varscan2
- ASIC5 | c.1234A>T p.R412W | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560740792; called by muse, varscan2
- CD40LG | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 61/585 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs145115086, COSV65698277; ClinVar: benign; called by muse, mutect2, varscan2
- CDH10 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 66/633 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.684); catalogued as rs560951980, COSV100049621, COSV52598944, COSV52600093; called by muse, mutect2, varscan2
- CFAP45 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); catalogued as rs776543202, COSV63649147; called by muse, mutect2
- CGA | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.94); catalogued as COSV63644400; called by muse, mutect2
- CHST3 | c.60G>C p.M20I | Missense Mutation (SNP) | VAF 96/846 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV64151173; called by muse, mutect2, varscan2
- COL11A1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 88/518 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1462597589, COSV100615721, COSV62191823; called by muse, mutect2, varscan2
- CSMD3 | c.3629C>T p.S1210L (on ENST00000297405 / NM_001363185.1; = p.S1106L on NM_052900.3) | Missense Mutation (SNP) | VAF 72/687 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749839773, COSV52105227; called by muse, mutect2, varscan2
- CXCL11 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs377189872, COSV60666552; called by muse, mutect2, varscan2
- DOCK2 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769663046, COSV56946543, COSV56987375; called by muse, mutect2, varscan2
- FLG | c.11090G>A p.R3697H | Missense Mutation (SNP) | VAF 104/1164 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs555710209; called by muse, mutect2, varscan2
- GLRA2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1275308465; called by muse, mutect2, varscan2
- HCLS1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58855262; called by muse, mutect2
- HFM1 | c.2458C>G p.L820V | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54023975; called by muse, mutect2, varscan2
- IL16 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770332586; called by muse, mutect2, varscan2
- KCNT2 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV54110145; called by muse, mutect2, varscan2
- LAMA1 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 107/615 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.157); catalogued as rs528185369, COSV67532208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LNPEP | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs763065052; called by muse, mutect2, varscan2
- MAP2K7 | c.986T>A p.F329Y | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607540; called by muse, mutect2
- MAP2K7 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101209008; called by muse, mutect2
- NAV2 | c.5089C>T p.R1697W (on ENST00000396087 / NM_001244963.2; = p.R1641W on NM_145117.5) | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs151080998, COSV100216568; called by muse, mutect2
- NELFCD | c.1730C>T p.T577M (on ENST00000602795; = p.T559M on NM_198976.4) | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as rs760408804; called by muse, mutect2, varscan2
- NLRP3 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 270/1449 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60221154; called by muse, mutect2, varscan2
- NXN | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 96/756 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200704586; called by muse, mutect2, varscan2
- ODF4 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 83/768 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs557908400; called by muse, mutect2, varscan2
- PDGFRA | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 58/427 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.284); catalogued as rs376544204, COSV57264427; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PGAP3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 329/2664 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99510679; called by muse, mutect2, varscan2
- PTP4A1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV101037687; called by muse, mutect2
- SHLD2 | c.2261A>C p.E754A | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV53953792; called by muse, mutect2
- SLC9A3R1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766649573; called by muse, mutect2, varscan2
- SMPD1 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.2836G>A p.A946T (on ENST00000367255 / NM_182961.4; = p.A953T on NM_033071.3) | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54981117; called by muse, mutect2, varscan2
- TENM2 | c.2638C>T p.R880W (on ENST00000518659 / NM_001122679.2; = p.R648W on NM_001080428.3) | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs748990955, COSV69133491; called by muse, mutect2, varscan2
- TMEM52 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 146/745 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1476662371; called by muse, mutect2, varscan2
- TRIM6 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs751430177, COSV53479532; called by muse, mutect2
- USP29 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54144387; called by muse, mutect2
- ZEB1 | c.2029C>G p.L677V | Missense Mutation (SNP) | VAF 77/770 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as rs267602469, COSV100314152; called by muse, mutect2
- ZNF700 | c.1474C>G p.H492D | Missense Mutation (SNP) | VAF 111/625 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99583481; called by muse, mutect2, varscan2
- AK5 | c.415+1G>T p.X139_splice (on ENST00000354567 / NM_174858.3; = p.X113_splice on NM_012093.4) | Splice Site (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- ATP1B4 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 74/633 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP6V1F | c.14dup p.K6* | Frame Shift Ins (INS) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- BIRC3 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC39 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2
- DNAJC21 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- EBF1 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1E1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- EP400 | c.4975C>G p.P1659A | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FKBP5 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- FOXP2 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 79/792 reads (10%) | called by muse, mutect2
- GCLC | c.578G>C p.R193T (on ENST00000643939; = p.R191T on NM_001498.4) | Missense Mutation (SNP) | VAF 76/680 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- GRIK2 | c.2030A>G p.Q677R | Missense Mutation (SNP) | VAF 58/598 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM1B | c.2391A>C p.A797= (on ENST00000449850; = p.A564= on NM_153042.4) | Splice Region (SNP) | VAF 16/99 reads (16%) | called by muse, varscan2
- KDM2A | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- MAP1S | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAPKAPK2 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5B | c.9584_9628del p.V3195_R3209del | In Frame Del (DEL) | VAF 80/1259 reads (6%) | called by mutect2, pindel
- MYH2 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 78/606 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NLRP12 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 104/789 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NPY2R | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRG1 | c.973G>C p.E325Q (on ENST00000405005 / NM_013964.5; = p.E330Q on NM_013956.5) | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ODR4 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- OR10H5 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTUD6B | c.372T>G p.I124M | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCNX1 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 99/936 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU4F1 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 60/609 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM44 | c.817G>T p.E273* (on ENST00000611254; = p.E907* on NM_001080504.2) | Nonsense Mutation (SNP) | VAF 42/374 reads (11%) | called by muse, mutect2, varscan2
- RFX7 | c.3953A>G p.D1318G (on ENST00000559447 / NM_001368074.1; = p.D1415G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.643); called by muse, mutect2
- RGS14 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIF1 | c.1581G>C p.L527F | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2
- SMG6 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRN4 | c.767_768dup p.L257Afs*37 | Frame Shift Ins (INS) | VAF 45/407 reads (11%) | called by mutect2, pindel, varscan2
- TAF3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TFEC | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 74/906 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- TLR5 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 76/828 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- TNFRSF6B | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TNIP1 | c.1381T>A p.L461M | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2
- TTN | c.7222C>A p.Q2408K (on ENST00000591111; = p.Q2362K on NM_003319.4) | Missense Mutation (SNP) | VAF 54/587 reads (9%) | PolyPhen benign (0.116); called by muse, mutect2
- ZNF311 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF804A | c.605A>C p.D202A | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADGRE2 | c.744C>T p.H248= | Silent (SNP) | VAF 42/465 reads (9%) | catalogued as rs776535410; called by muse, mutect2, varscan2
- ADGRL2 | c.2136T>A p.L712= (on ENST00000370717 / NM_001366005.1; = p.L699= on NM_012302.4) | Silent (SNP) | VAF 61/282 reads (22%) | called by muse, varscan2
- BBS9 | c.1002A>G p.R334= | Silent (SNP) | VAF 126/611 reads (21%) | called by muse, mutect2, varscan2
- CASKIN1 | c.480C>T p.R160= | Silent (SNP) | VAF 79/507 reads (16%) | catalogued as rs1428439987, COSV58878374; called by muse, mutect2, varscan2
- CAVIN4 | c.294T>G p.A98= | Silent (SNP) | VAF 38/280 reads (14%) | called by muse, mutect2, varscan2
- CBX6 | c.526C>T p.L176= | Silent (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- CCPG1 | c.534C>T p.R178= | Silent (SNP) | VAF 42/402 reads (10%) | called by muse, mutect2
- CFAP43 | c.2400T>C p.V800= | Silent (SNP) | VAF 26/181 reads (14%) | called by muse, mutect2, varscan2
- ERICH6 | c.1809C>A p.I603= | Silent (SNP) | VAF 32/379 reads (8%) | catalogued as COSV55799986; called by muse, mutect2
- HECW1 | c.3687C>G p.A1229= | Silent (SNP) | VAF 44/566 reads (8%) | called by muse, mutect2
- HEPH | c.324G>T p.G108= (on ENST00000343002; = p.G162= on NM_138737.5) | Silent (SNP) | VAF 26/283 reads (9%) | catalogued as COSV57960550; called by muse, mutect2
- IARS2 | c.972T>G p.S324= | Silent (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- KCNH4 | c.1707G>A p.S569= | Silent (SNP) | VAF 70/1725 reads (4%) | catalogued as rs757602415; called by muse, mutect2
- MAP1S | c.2109G>A p.E703= | Silent (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- NLRP11 | c.2472G>A p.T824= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as rs370425219, COSV100789633; called by muse, mutect2, varscan2
- PKP3 | c.465T>C p.P155= | Silent (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- RP1 | c.2871T>C p.D957= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- SLC3A1 | c.1782C>T p.I594= | Silent (SNP) | VAF 41/444 reads (9%) | catalogued as rs373561366, COSV53218020; called by muse, mutect2
- SMARCA5 | c.3135A>G p.G1045= | Silent (SNP) | VAF 60/458 reads (13%) | called by muse, mutect2, varscan2
- SNX27 | c.384G>A p.L128= | Silent (SNP) | VAF 68/748 reads (9%) | called by muse, mutect2
- TCF20 | c.1827C>T p.S609= | Silent (SNP) | VAF 44/527 reads (8%) | catalogued as COSV59490731; called by muse, mutect2
- USP26 | c.2415G>A p.K805= | Silent (SNP) | VAF 60/499 reads (12%) | called by muse, mutect2, varscan2
- ZIC3 | c.522G>A p.S174= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as COSV54973791; called by muse, mutect2
- ZNF587B | c.879T>C p.T293= | Silent (SNP) | VAF 40/484 reads (8%) | called by muse, mutect2
- ZSWIM9 | c.474C>T p.F158= | Silent (SNP) | VAF 88/804 reads (11%) | catalogued as rs1376208712, COSV60888153; called by muse, mutect2, varscan2
- AC062028.1 | n.847A>C | RNA (SNP) | VAF 42/337 reads (12%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1169T>G | RNA (SNP) | VAF 42/369 reads (11%) | called by muse, mutect2, varscan2
- BET1-AS1 | n.225+6380A>T | Intron (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- BOLA3 | c.54+68G>T | Intron (SNP) | VAF 63/510 reads (12%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 68/722 reads (9%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2
- FUNDC2P2 | n.257G>T | RNA (SNP) | VAF 58/583 reads (10%) | called by muse, mutect2, varscan2
- GTF2IP4 | n.1387G>A | RNA (SNP) | VAF 58/704 reads (8%) | catalogued as rs1320203986; called by muse, mutect2
- MIR7162 | chr10:30365238 T>C | 3'Flank (SNP) | VAF 71/618 reads (11%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-71C>G | Intron (SNP) | VAF 14/127 reads (11%) | catalogued as rs1292648613; called by muse, mutect2
- SPART | c.-3+1833_-3+1848del | Intron (DEL) | VAF 24/167 reads (14%) | called by mutect2, pindel
- TPD52 | c.506+39G>A | Intron (SNP) | VAF 61/310 reads (20%) | catalogued as rs746261138; called by muse, mutect2, varscan2
